Somatic mutation profile of tumor specimen MMRF_2678_1_BM_CD138pos (aliquot MMRF_2678_1_BM_CD138pos_T1_KHS5U_L13798) from MMRF case MMRF_2678, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,109 days).
Specimen MMRF_2678_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b8b95b3-8104-405b-bfac-e4987b2bc39c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2678_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2678_1_PB_WBC_C3_KHS5U_L13799; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/082bd0a7-b47e-4b71-8c43-2707e5b9166e

The open-access MAF lists 112 somatic variants for this specimen: 47 protein-altering or splice-affecting, 17 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 23, Silent 17, Intron 11, 5'UTR 6, Nonsense Mutation 3, 5'Flank 3, RNA 3, 3'Flank 2, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANKAR | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV99854202; called by muse, mutect2, varscan2
- FCGBP | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs571102428; called by muse, mutect2, varscan2
- GABRG1 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs563170566, COSV54953043; called by muse, varscan2
- IGHV2-70 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs374979633; called by muse, varscan2
- IGHV2-70 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs566067300; called by muse, varscan2
- IGLL5 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.952); catalogued as rs745485743, COSV73251123; called by muse, mutect2, varscan2
- IGLL5 | c.206+1G>C p.X69_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as rs769556163, COSV73249537, COSV73250119, COSV73251144; called by muse, mutect2, varscan2
- IGLV3-1 | c.145A>T p.K49* | Nonsense Mutation (SNP) | VAF 74/198 reads (37%) | catalogued as rs192957059; called by muse, varscan2
- IGLV3-1 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs61731694; called by muse, varscan2
- MICAL2 | c.2790G>T p.K930N | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs760026959, COSV104373233; called by mutect2, varscan2
- PRSS38 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764249929; called by muse, mutect2, varscan2
- PTPN14 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 63/259 reads (24%) | catalogued as COSV100872424; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1633T>C p.F545L | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs772271308; called by muse, mutect2, varscan2
- RBP3 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs376396466; called by muse, mutect2, varscan2
- SDR9C7 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as rs537510334, COSV53288812; called by muse, mutect2, varscan2
- SIM1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs1165826114, COSV53490948; called by muse, mutect2, varscan2
- TAP2 | c.-3G>A | Splice Region (SNP) | VAF 15/117 reads (13%) | catalogued as rs1388558033; called by muse, mutect2, varscan2
- TWNK | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 10/223 reads (4%) | catalogued as rs1382829987; called by muse, mutect2
- UNC93A | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs536332358, COSV57808510; called by muse, varscan2
- XYLT1 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762539720; called by muse, mutect2, varscan2
- ZNF462 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52943705; called by muse, varscan2
- ABCC5 | c.4211A>C p.Q1404P | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ANO1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- APBA1 | c.1016G>C p.S339T | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2
- APOB | c.10409A>T p.Y3470F | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by mutect2, varscan2
- C10orf99 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARD11 | c.3411C>G p.D1137E | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDRT1 | c.1973A>T p.D658V | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- COL5A1 | c.5242C>A p.Q1748K | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.203); called by mutect2, varscan2
- CREG2 | c.686del p.P229Qfs*4 | Frame Shift Del (DEL) | VAF 64/346 reads (18%) | called by mutect2, pindel, varscan2
- CTIF | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CYP2C8 | c.686C>G p.T229S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFR3A | c.1285A>C p.T429P | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYS | c.4194A>C p.L1398F | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FBLN2 | c.3542C>T p.T1181I | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HMCN1 | c.5743G>T p.V1915F | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by mutect2, varscan2
- IGHV2-70 | c.168delinsAAG p.S56Rfs*30 | Frame Shift Ins (INS) | VAF 48/130 reads (37%) | called by pindel, varscan2*
- IGKV4-1 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- IGKV4-1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRC14 | c.1001A>G p.H334R | Missense Mutation (SNP) | VAF 141/347 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PTPRU | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RAPGEFL1 | c.1634T>A p.F545Y | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SASH1 | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC35G3 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- SYNGR1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC7A | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by mutect2, varscan2
- C19orf25 | c.199C>A p.R67= | Silent (SNP) | VAF 57/168 reads (34%) | called by muse, mutect2, varscan2
- CEP152 | c.4644A>G p.A1548= (on ENST00000380950 / NM_001194998.2; = p.A1492= on NM_014985.4) | Silent (SNP) | VAF 77/377 reads (20%) | catalogued as rs1566971188; called by muse, mutect2, varscan2
- DCLK1 | c.39C>T p.D13= | Silent (SNP) | VAF 152/386 reads (39%) | catalogued as rs756293091, COSV55189185; called by muse, varscan2
- DERL3 | c.297C>T p.F99= | Silent (SNP) | VAF 206/528 reads (39%) | called by muse, mutect2, varscan2
- FOXO1 | c.54C>G p.P18= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- KCNH8 | c.1227C>T p.N409= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs1286863809; called by muse, mutect2, varscan2
- KIAA1755 | c.2370C>T p.A790= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs1260600832; called by muse, mutect2, varscan2
- KRT2 | c.876C>T p.A292= | Silent (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- LAMA1 | c.8067G>A p.K2689= | Silent (SNP) | VAF 118/266 reads (44%) | called by muse, mutect2, varscan2
- LAMB2 | c.126T>C p.C42= | Silent (SNP) | VAF 49/180 reads (27%) | called by muse, mutect2, varscan2
- NCBP1 | c.2367G>A p.Q789= | Silent (SNP) | VAF 233/412 reads (57%) | catalogued as COSV64305171; called by muse, mutect2, varscan2
- NLRC3 | c.621G>A p.A207= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs188485174; called by muse, mutect2, varscan2
- PISD | c.906C>T p.N302= (on ENST00000439502 / NM_001326412.1; = p.N268= on NM_014338.3) | Silent (SNP) | VAF 107/273 reads (39%) | catalogued as rs534038476; called by muse, mutect2, varscan2
- TGFB1I1 | c.618C>A p.T206= (on ENST00000394863 / NM_001042454.3; = p.T189= on NM_015927.4) | Silent (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- TTC6 | c.3177G>A p.G1059= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- VCAN | c.702T>G p.S234= | Silent (SNP) | VAF 84/307 reads (27%) | called by muse, mutect2, varscan2
- XYLT2 | c.2506C>T p.L836= | Silent (SNP) | VAF 99/205 reads (48%) | catalogued as rs1330480196; called by muse, mutect2, varscan2
- ACTN1 | c.*58G>A | 3'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as rs1033705565; called by muse, mutect2, varscan2
- ATL3 | chr11:63671525 C>T | 5'Flank (SNP) | VAF 3/37 reads (8%) | catalogued as rs948047438; called by muse, mutect2
- BIN2 | c.313-112C>T | Intron (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- CALD1 | c.1794+12G>T | Intron (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- CCDC68 | chr18:54903005 C>A | 3'Flank (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- CDK16 | c.-382G>A | 5'UTR (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- CENPP | c.*3680G>A | 3'UTR (SNP) | VAF 66/262 reads (25%) | called by muse, mutect2, varscan2
- CPB1 | chr3:148827738 C>A | 5'Flank (SNP) | VAF 122/409 reads (30%) | called by mutect2, varscan2
- DNAJC1 | c.-263C>T | 5'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- ECI1 | c.52+11C>T | Intron (SNP) | VAF 41/89 reads (46%) | catalogued as rs988881339; called by muse, mutect2
- FBXO7 | c.-12C>T | 5'UTR (SNP) | VAF 18/35 reads (51%) | catalogued as rs1388445759; called by muse, mutect2, varscan2
- GNL1 | c.*4386C>T | 3'UTR (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- GPR158 | c.*2940A>G | 3'UTR (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- GPRC5C | chr17:74449889 C>A | 3'Flank (SNP) | VAF 77/162 reads (48%) | called by muse, mutect2, varscan2
- KCTD15 | c.*221G>A | 3'UTR (SNP) | VAF 51/195 reads (26%) | catalogued as rs539715824; called by muse, mutect2, varscan2
- LCE2A | c.*183C>G | 3'UTR (SNP) | VAF 68/155 reads (44%) | catalogued as COSV100909175; called by muse, mutect2, varscan2
- LPAR1 | c.*45A>G | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- MEGF8 | c.*1017A>C | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- MRS2 | c.*1370A>G | 3'UTR (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- NHSL1 | c.676+4993C>T | Intron (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
- NUP54 | c.*306T>A | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- OCSTAMP | c.-46C>T | 5'UTR (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*526T>A | 3'UTR (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- PARD6G | c.-10G>A | 5'UTR (SNP) | VAF 75/204 reads (37%) | called by muse, mutect2, varscan2
- PIK3C2A | c.*2068T>C | 3'UTR (SNP) | VAF 33/119 reads (28%) | catalogued as rs925900517; called by muse, mutect2, varscan2
- PPFIA4 | c.1633-73A>G | Intron (SNP) | VAF 2/17 reads (12%) | called by muse, mutect2
- PRKRIP1 | c.*752G>A | 3'UTR (SNP) | VAF 90/205 reads (44%) | called by muse, mutect2, varscan2
- RAB5A | c.*959A>G | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- REXO5 | c.-2-59G>A | Intron (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- RHBDF2 | c.1998-28G>A | Intron (SNP) | VAF 21/45 reads (47%) | catalogued as rs1233207649; called by muse, mutect2, varscan2
- RLIM | c.*5812C>G | 3'UTR (SNP) | VAF 3/33 reads (9%) | catalogued as rs1396380613; called by muse, mutect2
- S100A2 | c.-10-78G>A | Intron (SNP) | VAF 27/53 reads (51%) | catalogued as rs759894077; called by muse, mutect2, varscan2
- SFXN3 | c.*385T>C | 3'UTR (SNP) | VAF 46/117 reads (39%) | called by muse, mutect2, varscan2
- SH3BP2 | c.357+84C>T | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- SSPOP | n.8217G>A | RNA (SNP) | VAF 77/268 reads (29%) | catalogued as rs1157929859, COSV65138202; called by muse, mutect2, varscan2
- SUSD6 | c.*2752_*2758del | 3'UTR (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- SYNGR2P1 | n.298C>T | RNA (SNP) | VAF 106/935 reads (11%) | catalogued as rs1032406703; called by muse, mutect2, varscan2
- THY1 | c.*1357A>G | 3'UTR (SNP) | VAF 13/336 reads (4%) | catalogued as rs1395997062; called by muse, mutect2
- TMSB4X | c.*69C>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- TRAM2 | c.*560dup | 3'UTR (INS) | VAF 89/338 reads (26%) | called by mutect2, pindel, varscan2
- TSC22D4 | c.-238A>G | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- UCP3 | c.*981G>A | 3'UTR (SNP) | VAF 114/204 reads (56%) | catalogued as rs750624544; called by mutect2, varscan2
- UNC5D | c.*3343C>T | 3'UTR (SNP) | VAF 29/42 reads (69%) | called by muse, mutect2, varscan2
- UPK1B | c.*641G>T | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ZNF254 | c.253+116C>T | Intron (SNP) | VAF 46/154 reads (30%) | called by muse, mutect2
- ZNF658B | n.1103G>C | RNA (SNP) | VAF 41/317 reads (13%) | called by muse, mutect2, varscan2
- ZNF726 | c.226+536C>T | Intron (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280765 G>A | 5'Flank (SNP) | VAF 88/230 reads (38%) | called by muse, varscan2
